CCG case CUPP-B395 — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/df7985b3-d825-4528-9511-0283e8fa6ded

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Year of birth: 1951; Vital status: Alive.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Bone, NOS; Classification of tumor: metastasis; Age at diagnosis: 65.6 years (23,950 days); Year of diagnosis: 2017; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: TX; AJCC clinical M: M1; AJCC clinical stage: Stage III; AJCC pathologic T: TX; AJCC pathologic M: M1; AJCC pathologic stage: Stage III; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Brain, NOS / Bone, NOS.
   Pathology details: Consistent pathology review: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Timepoint category: First Treatment.
2. Progression (histology not recorded by GDC). Age at diagnosis: 66.5 years (24,300 days); Year of diagnosis: 2018; Days to diagnosis: 350 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80; ECOG performance status: 1.
- Day 350 (progression): Progression or recurrence: Yes; Days to progression: 350 days.
- Follow-up contact recording only the day: day 616.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 54 kg; Height: 163 cm; BMI: 20.3.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 30.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B395-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen.
- Sample CUPP-B395-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B395-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
